Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A821, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A821-01A (Primary Tumor).

Date:

Translate on from the original pathology evaluated on .

Right Adrenalectomy

Macroscopy

1) Adrenalectomy

The surgical specimen weight is 75g; the size is 7.5x6x3.5 cm and it contains a mass of 50x50x35mm. To note, there is the presence of adrenal gland at periphery.

2) Lymph node of the hepatic pedicle.

3) Gallbladder.

Microscopy

1) Adrenalectomy

The tumor consists of tumoral cells characterized by: big size, clear cytoplasm, nuclei containing thickened chromatin, clear nucleolus and clear and abundant cytoplasm. We note: moderate nuclear atypia and 5 mitoses/ 50 HPF. The architecture is trabecular with a vascular stroma. Absence of necrosis. At periphery, the tumor is delimited by a fibrous pseudo-capsule or it infiltrates adipose tissue. The tumor includes some nervous fibres without real invasion. We do not observe vascular invasion.

2) Lymph node of the hepatic pedicle: negative.

3) Gallbladder: normal.

Conclusion

Adrenalectomy: Malignant pheochromocytoma (50x50x30mm). Absence of vascular invasion.

Negative lymph node of the hepatic pedicle.

Normal gallbladder.

ICD-O-3
Pheochromocytoma, malignant
Site: (R) Adrenal gland NOS
8700/3
C74.9
9/10/17/13

Source: NCI Genomic Data Commons file 94c9b64a-f388-449e-b502-62461c08a2dd (TCGA-WB-A821.FC8BC717-CD26-45C0-B170-CC4748D70D2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).